Somatic mutation profile of tumor specimen TARGET-20-PARTYK-03A (aliquot TARGET-20-PARTYK-03A-01D) from TARGET case TARGET-20-PARTYK, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.4 years (1,967 days).
Specimen TARGET-20-PARTYK-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c338820c-bac2-4771-82b9-df0e5649e700.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARTYK-14A (Bone Marrow Normal), aliquot TARGET-20-PARTYK-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/63bf03a9-510d-4486-ad42-96a50946c354

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Nonsense Mutation 1, Frame Shift Ins 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GATA2 | c.1131C>A p.Y377* | Nonsense Mutation (SNP) | VAF 21/91 reads (23%) | catalogued as CD141169; called by muse, mutect2, varscan2
- NPM1 | c.863_864insCCTG p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 24/60 reads (40%) | catalogued as rs1554138189, COSV51543231, COSV51545499, COSV51554041, COSV51557774, COSV51563665; called by mutect2, pindel, varscan2
- FLT3 | c.2508_2509insGGC p.I836_M837insG | In Frame Ins (INS) | VAF 38/288 reads (13%) | called by mutect2, pindel, varscan2
